Surgical pathology report (de-identified scan), TCGA case TCGA-44-5643, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-5643-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN

- A. Right lower lobe tissue procurement
- B. Completion right pneumonectomy
- C. Level 7 lymph node
- D. 4R lymph node
- E. Mediastinal cyst
- F. 2R lymph node
- G. Superior vein stump

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer.
POST-OP DIAGNOSIS: Lung cancer.

GROSS DESCRIPTION

A. Received fresh labeled "right lower lobe" is a 363-gram, 19 x 11 x 5.5 cm lobectomy specimen with attached 1 cm in length, 1.8 x 1.4 cm in diameter bronchial stump. The pleura is smooth glistening tan-pink and focally retracted with a subjacent palpable mass lesion. On sectioning, there is a well-circumscribed, 6.8 x 6.5 x 5 cm focally cystic tan-white lesion, which focally approaches the inked pleural surface within less than 0.1 cm. A portion of tumor and a portion of normal tissue are submitted for tissue procurement, as requested. In addition, the tumor extends to within 2 cm of the bronchial stump margin. The remaining parenchyma is spongiform, red-purple, with a 4-cm ill-defined, focus of consolidation inferior to the tumor (see block 10). No additional abnormality is noted. Three slight rubbery tan-gray-black tissue in keeping with lymph nodes measuring up 1.3 cm in greatest dimension are recovered from the hilar region. Representative sections are submitted in 12 blocks as labeled. RS-12.

BLOCK SUMMARY: 1 - Bronchial stump margin, 2 - vascular margin, 3-5 - tumor to inked pleural surface, 6 - tumor to bronchial stump, 7 - central tumor, 8 - tumor to normal, 9 - random normal, 10 - area of

[page 2 of 4]
1

GROSS DESCRIPTION

consolidated, 11 - two whole lymph nodes, 12 - one trisected lymph node.

B. Received fresh, labeled "completion right pneumonectomy" is a 223 gram, 13.5 x 10.5 x 6.0 cm. lobectomy specimen with attached 2.5 cm. in length, 2.8 x 1.8 cm. in diameter bronchial stump. The pleura is wrinkled pink purple. On sectioning the parenchyma is spongiform red purple with scant diffuse anthracosis. No discrete mass lesion or abnormality is identified. Four slightly rubbery tan gray-black tissues in keeping with lymph nodes measuring up to 1.8 cm. in greatest dimension are recovered from the hilum. Representative sections are submitted in 7 blocks as labeled. RS7.

BLOCK SUMMARY: 1 - Bronchial stump margin; 2 - vascular margin; 3-5 - random parenchyma; 6 - three whole peripheral nodes; 7 - trisected largest perihilar lymph node.

C. Received fresh, labeled "level 7 lymph node" are four intact to slightly fragmented soft pale tan to tan red tissue in keeping with lymph nodes ranging from 0.7 cm. in greatest dimension up to 4.5 x 2.8 x 1.3 cm. (the largest possibly representing a nodule aggregate). The specimen is entirely submitted in five blocks as labeled. AS-5.

BLOCK SUMMARY: 1 - Three whole tissues; 2-5 - section largest tissue.

D. Received fresh, labeled "4R lymph nodes" are two soft tan white to tan red tissues measuring 0.7 and 1.3 cm. in greatest dimension which are submitted in toto. AS-1.

E. Received fresh, labeled "mediastinal cyst" are four diffusely cauterized slightly rubbery white pink tissue fragments averaging 1.3 x 0.8 x 0.15 cm. The specimens are bisected and entirely submitted in two blocks.

F. Received fresh, labeled "2R lymph nodes" are two diffusely cauterized fragmented, soft golden yellow fatty portions of tissue measuring 1.3 and 1.8 cm. in greatest dimension. No definitive lymphoid tissues are recovered. The specimens are submitted in toto independently in two blocks. AS-2.

G. Received fresh, labeled "superior vein stump" is an irregular, 0.6 x 0.4 x 0.15 cm. fragment of rubbery white pink tissue with numerous silver metallic staples. The staples are and the specimen is entirely submitted in one block. AS-1.

[page 3 of 4]
MICROSCOPIC DESCRIPTION

Histologic type: Non-small cell carcinoma.
Histologic grade: Poorly differentiated.
Primary tumor (pT): Tumor measures maximally 6.8 cm in size and is confined to the lung (pT2b).
Margins of resection: Negative.
Direct extension of tumor: Absent.
Venous (large vessel) invasion: Positive.
Arterial (large vessel) invasion: Negative.
Lymphatic (small vessel) invasion: Positive.
Regional lymph nodes (pN): Eight peribronchial and perihilar lymph nodes
are negative for metastatic carcinoma. One of four level 7
mediastinal
nodes contains metastatic adenocarcinoma. 4R and 2R lymph nodes
are
negative for tumor (pN2).
Distant metastasis (pM): Cannot be assessed (pMX).
Other findings: Post-obstructive pneumonitis and pulmonary edema
are
present. Benign mediastinal cyst.

5,4x2,3x3

DIAGNOSIS

A,B. Lung, right pneumonectomy:
Poorly differentiated non-small cell carcinoma involving
the
right lower lobe.
The bronchial and vascular margins of resection are free of
tumor. The tumor does not extend beyond the visceral
pleural surface. Lymphovascular space invasion and
medium-sized venous invasion by tumor is present.
Post-obstructive pneumonitis with pulmonary edema.
Eight peribronchial and perihilar lymph nodes negative for
metastatic carcinoma (0/8).

[page 4 of 4]
- C. Lymph nodes, level 7, resection:
One of four lymph nodes contains metastatic carcinoma (1/4).
- D. Lymph node, 4R, resection:
Single lymph node negative for metastatic carcinoma (0/1).
- E. Mediastinum, resection of lesion:
Benign fibrofatty tissue with a mesothelial-lined cyst.
Negative for malignancy.
- F. Lymph nodes, 2R, resection:
Two lymph nodes negative for metastatic carcinoma (0/2).
- G. Vein, superior vein stump, resection:

DIAGNOSIS

No significant histopathologic findings.
Negative for malignancy.

--- End Of Report ---

Source: NCI Genomic Data Commons file a0a1556f-ffc2-471e-abeb-d34171f7573f (TCGA-44-5643.3117A24B-6125-47A8-A05B-4ADA99E68DFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).